Somatic mutation profile of tumor specimen 0DFRTX from CCDI case PBBSKL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,622 days).
Specimen 0DFRTX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42907ae9-b37b-4689-83f9-45c4707f5edb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRTY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28de8184-adb8-49c4-b70e-2ff0c4e2ced0

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 207/1491 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C11orf1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 24/954 reads (3%) | catalogued as rs782010241, COSV52787941; called by muse, mutect2
- PCDHGA6 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 152/899 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.06); catalogued as rs1249141559; called by muse, mutect2, varscan2
- PDE6A | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 80/484 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs758708415, COSV54924569; called by muse, varscan2
- VWF | c.5177G>A p.R1726H | Missense Mutation (SNP) | VAF 133/1462 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs147313320; called by muse, mutect2
- ZBTB10 | c.1800A>G p.S600= | Silent (SNP) | VAF 114/709 reads (16%) | catalogued as COSV66948673; called by muse, mutect2, varscan2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 22/756 reads (3%) | called by muse, mutect2
- PDIA3 | c.-64C>G | 5'UTR (SNP) | VAF 14/179 reads (8%) | catalogued as rs1418930848; called by muse, mutect2
